CGCI case BLGSP-71-27-00414 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9fefdc8c-3dfc-4a08-80bc-5e8d773385dc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,627 days); Year of diagnosis: 2016; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 574 days (1.6 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Colon; Sites of involvement: Colon, NOS / Tonsil / Breast, NOS / Omentum.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 9.7 cm.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Iliac, NOS.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 3 days; Days to treatment end: 106 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 106 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 574 days (1.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -6,972.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1625 [Blood test normal range upper: 250].

Other clinical attributes
- Day -6,972: Comorbidities: HIV/AIDS.
- Day -6,972: Risk factors: HIV/AIDS.
- Day 0: Weight: 118.7 kg; Height: 175.5 cm; BMI: 38.5; CD4 count: 660; Haart treatment indicator: Yes; HIV viral load: 20.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 574: Nadir CD4 count: 725.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-27-00414-01A-01-S1-HE: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 30; Percent stromal cells: 5; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample BLGSP-71-27-00414-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-27-00414-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Extranodal involvment other: left tonsil, mammary, omentum; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: colon resection; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical; Lymph node involvement site: Iliac; Lymph node involvement site: para-aortic.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1625; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: BCL2.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: DA-EPOCH + Rituxumab; Pharma adjuvant cycles count: 6.
